Somatic mutation profile of tumor specimen TCGA-D7-6820-01A (aliquot TCGA-D7-6820-01A-11D-1882-08) from TCGA case TCGA-D7-6820, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.3 years (23,486 days).
Specimen TCGA-D7-6820-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be0d276d-aef1-4970-bebe-4c0d13ae6f0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6820-10A (Blood Derived Normal), aliquot TCGA-D7-6820-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df63dfc9-24be-4169-890c-6d204b252b38

The open-access MAF lists 89 somatic variants for this specimen: 59 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 27, Nonsense Mutation 8, Intron 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB4 | c.2780G>A p.R927Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as rs397514262, CM1311193, COSV61511188; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 39/102 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADSS1 | c.232A>T p.K78* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV58275403; called by muse, mutect2, varscan2
- ANKS1B | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as COSV61366951; called by muse, mutect2, varscan2
- ASXL2 | c.3139T>G p.S1047A | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.112); catalogued as COSV55464728; called by muse, mutect2, varscan2
- ATP1A1 | c.2264T>G p.F755C | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55193360; called by muse, mutect2, varscan2
- AXIN1 | c.1153C>G p.P385A | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51991354; called by muse, mutect2, varscan2
- CADPS | c.3365C>A p.T1122N | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs151301388; called by muse, mutect2, varscan2
- CCDC74A | c.191A>C p.H64P | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54608666; called by muse, mutect2, varscan2
- CFAP97 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 66/109 reads (61%) | SIFT tolerated (0.39); PolyPhen benign (0.113); catalogued as COSV57111699; called by muse, mutect2, varscan2
- COA8 | c.439T>A p.L147I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56029372; called by muse, mutect2, varscan2
- COL2A1 | c.4262T>C p.I1421T | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV61532936; called by muse, mutect2, varscan2
- CRYBG1 | c.4919G>A p.C1640Y | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.415); catalogued as COSV64813832; called by muse, mutect2, varscan2
- CTSD | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52588568; called by muse, mutect2, varscan2
- DGKA | c.2176dup p.R726Pfs*79 | Frame Shift Ins (INS) | VAF 17/111 reads (15%) | catalogued as rs748318989; called by mutect2, varscan2
- DTNB | c.1327C>G p.L443V | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV56482075; called by muse, mutect2, varscan2
- EPHA3 | c.1022T>C p.V341A | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60719994; called by muse, mutect2
- FILIP1L | c.608T>A p.L203* | Nonsense Mutation (SNP) | VAF 24/242 reads (10%) | catalogued as COSV58773606; called by muse, mutect2, varscan2
- FLG | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 202/584 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs200858156, COSV64243479; called by muse, mutect2, varscan2
- HOXB13 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV51706905; called by muse, mutect2, varscan2
- IGDCC3 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV60079301; called by muse, mutect2, varscan2
- IMMT | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54489021; called by muse, mutect2
- ITPR3 | c.2079G>C p.W693C | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV65413418; called by muse, mutect2, varscan2
- KCNJ14 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 54/93 reads (58%) | catalogued as rs781352540, COSV57308614; called by muse, mutect2, varscan2
- KIF2A | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66946350; called by muse, mutect2, varscan2
- KLHL18 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.674); catalogued as COSV51744015, COSV51747753; called by muse, mutect2, varscan2
- LCE2D | c.81G>C p.K27N | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.958); catalogued as COSV100909541, COSV64229161; called by muse, mutect2, varscan2
- LRRC29 | c.589A>G p.R197G | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs781356500, COSV58528036; called by muse, mutect2, varscan2
- MAP3K7 | c.410G>A p.C137Y | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65231686; called by muse, mutect2, varscan2
- MS4A14 | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV55737023; called by muse, mutect2, varscan2
- MYCBP2 | c.12592G>C p.D4198H (on ENST00000357337; = p.D4236H on NM_015057.5) | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1257434861, COSV62033137; called by muse, mutect2, varscan2
- MYH9 | c.3803G>A p.R1268H | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs768022369, COSV53391295, COSV99339704; called by muse, mutect2, varscan2
- MYO18B | c.2960C>T p.T987M | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs371198573; called by muse, mutect2, varscan2
- NALCN | c.1901T>G p.F634C | Missense Mutation (SNP) | VAF 121/415 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51953703, COSV51955356; called by muse, mutect2, varscan2
- NANP | c.236C>G p.A79G | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV59160516; called by muse, mutect2
- NHLH1 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV57484148; called by muse, mutect2, varscan2
- OASL | c.1411A>T p.K471* | Nonsense Mutation (SNP) | VAF 45/118 reads (38%) | catalogued as COSV56568128; called by muse, mutect2, varscan2
- OR4A15 | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.159); catalogued as COSV59036851; called by muse, mutect2, varscan2
- OR51M1 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.278); catalogued as rs374491977; called by muse, mutect2, varscan2
- PTPN11 | c.407T>A p.L136H | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61011680; called by muse, mutect2, varscan2
- RBM28 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1217226897, COSV56164296; called by muse, mutect2
- RESF1 | c.2839A>G p.T947A | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV57024601; called by muse, mutect2, varscan2
- ROBO1 | c.4532T>C p.L1511P | Missense Mutation (SNP) | VAF 11/313 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.276); catalogued as COSV71397284; called by muse, mutect2
- SLC7A14 | c.272T>A p.F91Y | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51587313; called by muse, mutect2, varscan2
- SP8 | c.511G>A p.G171R (on ENST00000361443 / NM_198956.4; = p.G189R on NM_182700.6) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs748563164, COSV63866727; called by muse, mutect2
- SSTR4 | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54799550; called by muse, mutect2, varscan2
- SUSD5 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV58879806; called by muse, mutect2, varscan2
- SYNGR2 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV99857349; called by muse, mutect2
- TAF4 | c.1952C>G p.P651R | Missense Mutation (SNP) | VAF 66/365 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53341386; called by muse, mutect2, varscan2
- TBC1D25 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV100952156, COSV65124309; called by muse, mutect2, varscan2
- TECTA | c.5129C>T p.P1710L | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV50769590; called by muse, mutect2
- TFPI | c.611A>T p.K204M | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV51900901, COSV51904367; called by muse, mutect2, varscan2
- THBS2 | c.2434C>T p.R812* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as rs757104686, COSV64678844; called by muse, mutect2, varscan2
- TRPA1 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV51570282; called by muse, mutect2, varscan2
- ULK1 | c.233T>A p.L78Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277403590, COSV58859150; called by muse, mutect2, varscan2
- WWC1 | c.2192G>A p.W731* | Nonsense Mutation (SNP) | VAF 50/113 reads (44%) | catalogued as COSV54656576; called by muse, mutect2, varscan2
- XRN2 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as COSV65871025; called by muse, mutect2, varscan2
- ZNF512 | c.1188G>A p.W396* | Nonsense Mutation (SNP) | VAF 51/221 reads (23%) | catalogued as COSV62677483; called by muse, mutect2, varscan2
- MYF5 | c.742del p.S248Pfs*16 | Frame Shift Del (DEL) | VAF 18/118 reads (15%) | called by mutect2, pindel, varscan2
- ADORA1 | c.480C>T p.G160= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs1440293049, COSV55142277; called by muse, mutect2, varscan2
- ANKRD12 | c.1749T>C p.Y583= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as COSV50839058; called by muse, mutect2, varscan2
- ATP11B | c.1806C>G p.L602= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV60028406, COSV60032057; called by muse, mutect2, varscan2
- BCL6B | c.252C>T p.P84= | Silent (SNP) | VAF 97/197 reads (49%) | catalogued as rs1346108273, COSV53429033; called by muse, mutect2, varscan2
- BORA | c.297T>A p.P99= (on ENST00000613797; = p.P24= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/293 reads (33%) | catalogued as COSV64695670; called by muse, mutect2, varscan2
- CEBPZ | c.456T>C p.N152= | Silent (SNP) | VAF 66/200 reads (33%) | catalogued as COSV50018454; called by muse, mutect2, varscan2
- CFAP77 | c.450C>T p.H150= | Silent (SNP) | VAF 64/115 reads (56%) | catalogued as rs759081377, COSV58014883; called by muse, mutect2, varscan2
- COL6A3 | c.3750C>T p.Y1250= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs763648429, COSV55102627; ClinVar: likely benign; called by muse, mutect2, varscan2
- DEFB135 | c.153C>T p.N51= | Silent (SNP) | VAF 284/343 reads (83%) | catalogued as rs368213237, COSV66363427, COSV66363628; called by muse, mutect2, varscan2
- ELOA3C | c.651C>T p.V217= | Silent (SNP) | VAF 35/1050 reads (3%) | catalogued as COSV55305251; called by muse, mutect2
- F13B | c.1530G>T p.V510= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV66373690, COSV66375218; called by muse, varscan2
- FSIP2 | c.20118G>T p.T6706= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV58090474, COSV58100545; called by muse, mutect2, varscan2
- KCTD1 | c.642A>G p.G214= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV58689690; called by muse, mutect2, varscan2
- OR8D2 | c.471A>G p.T157= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs560961386, COSV62488864; called by muse, mutect2, varscan2
- PAPPA2 | c.3981G>C p.V1327= | Silent (SNP) | VAF 40/259 reads (15%) | catalogued as COSV62807138; called by muse, mutect2, varscan2
- PCDHA11 | c.1899G>A p.T633= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV56475242; called by muse, mutect2, varscan2
- PCF11 | c.483G>A p.V161= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV53536068; called by muse, mutect2, varscan2
- PCSK4 | c.474C>T p.D158= | Silent (SNP) | VAF 81/143 reads (57%) | catalogued as rs758614207, COSV52012546, COSV52014677; called by muse, mutect2, varscan2
- PDZD8 | c.813C>T p.I271= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV57827704; called by muse, mutect2, varscan2
- SLC16A9 | c.417G>A p.A139= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs767859848, COSV68098386; called by muse, mutect2, varscan2
- SMAP1 | c.705G>A p.T235= (on ENST00000370455 / NM_001044305.3; = p.T208= on NM_021940.5) | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as rs753925599, COSV57638322; called by muse, mutect2, varscan2
- SRGAP3 | c.846G>A p.R282= | Silent (SNP) | VAF 12/181 reads (7%) | catalogued as COSV64537561; called by muse, mutect2
- TFDP3 | c.405C>T p.G135= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as rs369336277, COSV59536697; called by muse, mutect2, varscan2
- TRIM9 | c.1377G>A p.T459= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs200192609; called by muse, mutect2, varscan2
- ZBTB4 | c.666C>T p.A222= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs773818635, COSV60982633; called by muse, mutect2, varscan2
- ZNF132 | c.2016G>A p.R672= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as COSV54235818; called by muse, mutect2, varscan2
- ZNF521 | c.2751C>A p.A917= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV64130346; called by muse, mutect2
- NRG1 | c.502+31132G>A | Intron (SNP) | VAF 80/179 reads (45%) | catalogued as COSV99828976; called by muse, mutect2, varscan2
- SNORD116-16 | n.73T>G | RNA (SNP) | VAF 68/242 reads (28%) | called by muse, mutect2, varscan2
- TMC5 | c.1049-3355C>T | Intron (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99572728; called by mutect2, varscan2
